Somatic mutation profile of tumor specimen ALCH-B1ZR-TTP1-A (aliquot ALCH-B1ZR-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.4 years (20,217 days).
Specimen ALCH-B1ZR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a1b8be1-aa54-473c-a555-c5cda885b23e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZR-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZR-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10fb8092-fd57-4503-8b0e-cb316320e3e9

The open-access MAF lists 132 somatic variants for this specimen: 88 protein-altering or splice-affecting, 27 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 27, Nonsense Mutation 7, Intron 6, 3'UTR 3, 5'Flank 3, RNA 3, Splice Site 3, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 34/444 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2
- AKAP6 | c.532A>G p.R178G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55212432; called by muse, mutect2
- AMER1 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57657714, COSV57666586; called by muse, mutect2
- ATP10A | c.2038G>T p.E680* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV63516024; called by muse, mutect2
- ATP11A | c.1798C>A p.R600S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV99370525; called by muse, mutect2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2
- CALCB | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV60834429; called by muse, mutect2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 29/140 reads (21%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2, varscan2
- CREBBP | c.4232G>T p.G1411V | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116481, COSV52117966; called by muse, mutect2
- CREBBP | c.4231G>T p.G1411* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | catalogued as COSV52118491, COSV52144101; called by muse, mutect2
- DNAH5 | c.12838G>T p.D4280Y | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1264255228; called by muse, mutect2
- DNAH6 | c.11689G>A p.V3897I | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750884351; called by muse, mutect2
- GPR63 | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV57740562; called by muse, mutect2, varscan2
- HAUS7 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781885664; called by muse, mutect2, varscan2
- KNG1 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV99405655; called by muse, mutect2
- MYF6 | c.314G>T p.R105M | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57352572; called by muse, mutect2
- MYH1 | c.3766C>A p.L1256I | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV56846596; called by muse, mutect2
- OR1J2 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 17/347 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV58944364; called by muse, mutect2
- OR6T1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1249409115, COSV100189850; called by muse, mutect2
- PCDHA8 | c.2107G>T p.A703S | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.668); catalogued as rs781895761; called by muse, mutect2
- PLXNA4 | c.3796G>T p.E1266* | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV58105135; called by muse, mutect2
- RTTN | c.3258G>C p.R1086S | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV99732340; called by muse, mutect2
- SATB2 | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV53477248; called by muse, mutect2
- SDR9C7 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53290244; called by muse, mutect2
- WDR87 | c.4654C>T p.R1552W | Missense Mutation (SNP) | VAF 9/301 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1174955165; called by muse, mutect2
- ZBTB46 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs375790108; called by muse, mutect2
- ZNF292 | c.6393G>T p.L2131F | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100370229; called by muse, mutect2, varscan2
- AC011487.2 | n.965+1del | Splice Site (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- ACTN2 | c.1073C>G p.P358R | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACVR2B | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.36); called by muse, mutect2
- AFF2 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ALDOB | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- ARIH1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2
- ARMC4 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2
- C4orf54 | c.4534C>A p.R1512S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); called by muse, mutect2
- CADM3 | c.305T>C p.L102P (on ENST00000368125 / NM_001127173.3; = p.L136P on NM_021189.5) | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CALHM3 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2
- CCDC96 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CDH11 | c.406A>T p.N136Y | Missense Mutation (SNP) | VAF 41/646 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CDH19 | c.2037G>T p.R679S | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.266); called by muse, mutect2
- CLCNKB | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- COL4A3 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLG2 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EIF2AK4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- FAM117A | c.639C>G p.S213R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FANCA | c.3410G>A p.G1137D | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXN1 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- FSIP2 | c.11841G>T p.Q3947H | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- GALNT13 | c.1430C>A p.T477N | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.84); called by muse, mutect2
- GAS6 | c.886T>G p.Y296D | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- GNAT3 | c.96A>T p.R32S | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); called by muse, mutect2
- GRIA2 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.724); called by muse, mutect2
- H1-3 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- HSPB3 | c.400T>A p.C134S | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGLV9-49 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- ITPR2 | c.6166C>G p.H2056D | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.367); called by muse, mutect2
- KIAA1109 | c.9440G>T p.G3147V | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2
- KRT74 | c.732T>A p.F244L | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP19-6 | c.45T>A p.C15* | Nonsense Mutation (SNP) | VAF 22/329 reads (7%) | called by muse, mutect2
- LHFPL6 | c.217T>A p.S73T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- MGAM2 | c.4123G>T p.D1375Y | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOSMO | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- MPHOSPH9 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MUC16 | c.27296C>T p.S9099L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.427); called by muse, mutect2
- MYCBP2 | c.9977G>T p.C3326F (on ENST00000357337; = p.C3364F on NM_015057.5) | Missense Mutation (SNP) | VAF 43/796 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.648); called by muse, mutect2
- MYO9A | c.7202G>A p.S2401N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); called by muse, mutect2
- OCRL | c.2232C>A p.H744Q | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- OR6S1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- OTUD7A | c.2602G>T p.G868C (on ENST00000307050 / NM_001382637.1; = p.G861C on NM_130901.3) | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.027); called by muse, mutect2
- PARD3B | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 22/557 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHKB | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- PPP1R9A | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2
- PTPRT | c.3548A>G p.N1183S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- SCAF11 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 23/467 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); called by muse, mutect2
- SCARA3 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SEC14L1 | c.2042+2T>A p.X681_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- SETD1B | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TK2 | c.173A>T p.Q58L (on ENST00000299697; = p.Q114L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2
- TMC1 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TRMT1L | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2
- UPF3B | c.1375A>G p.T459A (on ENST00000276201 / NM_080632.3; = p.T446A on NM_023010.3) | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- USH2A | c.4901T>C p.L1634P | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- WDR11 | c.995-1G>A p.X332_splice | Splice Site (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- ZIC2 | c.336del p.F113Sfs*105 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- ZNF302 | c.1097G>A p.C366Y (on ENST00000627982; = p.C287Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF333 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2
- ZNF726 | c.1844A>G p.H615R | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- AKAP6 | c.1282C>T p.L428= | Silent (SNP) | VAF 11/215 reads (5%) | called by muse, mutect2
- ANO4 | c.2475C>T p.A825= (on ENST00000392977 / NM_001286615.2; = p.A790= on NM_178826.4) | Silent (SNP) | VAF 23/371 reads (6%) | catalogued as COSV100152469; called by muse, mutect2
- ARMC5 | c.261A>G p.A87= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- C10orf71 | c.481A>C p.R161= | Silent (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- CACNA1H | c.4596G>A p.L1532= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- CNTNAP4 | c.2844C>T p.A948= | Silent (SNP) | VAF 15/446 reads (3%) | called by muse, mutect2
- CUL4B | c.543C>A p.T181= | Silent (SNP) | VAF 7/180 reads (4%) | called by muse, mutect2
- FCGR1A | c.1035A>G p.R345= | Silent (SNP) | VAF 22/608 reads (4%) | called by muse, mutect2
- FRG1 | c.402A>T p.P134= | Silent (SNP) | VAF 26/470 reads (6%) | catalogued as COSV57008177; called by muse, mutect2
- GAS2 | c.333C>T p.D111= | Silent (SNP) | VAF 16/373 reads (4%) | catalogued as COSV99534467; called by muse, mutect2
- GET4 | c.976C>T p.L326= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- GPR45 | c.408C>T p.I136= | Silent (SNP) | VAF 23/267 reads (9%) | catalogued as rs770278854; called by muse, mutect2
- LRP2 | c.8095C>A p.R2699= | Silent (SNP) | VAF 41/604 reads (7%) | catalogued as rs1236195196; called by muse, mutect2
- MAMLD1 | c.639C>T p.P213= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs782134984; called by muse, mutect2
- PCDHB4 | c.639G>A p.A213= | Silent (SNP) | VAF 12/191 reads (6%) | catalogued as COSV52022192; called by muse, mutect2
- PCSK6 | c.453G>T p.V151= | Silent (SNP) | VAF 14/473 reads (3%) | called by muse, mutect2
- PSMD14 | c.810G>A p.L270= | Silent (SNP) | VAF 29/528 reads (5%) | called by muse, mutect2
- RABL3 | c.246A>T p.A82= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- RRP7A | c.615G>A p.K205= | Silent (SNP) | VAF 4/78 reads (5%) | called by muse, mutect2
- RYR3 | c.5568G>T p.A1856= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV101213504; called by muse, mutect2
- SLC16A10 | c.1377C>A p.P459= | Silent (SNP) | VAF 55/482 reads (11%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.441G>A p.G147= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as rs143302249; called by muse, mutect2
- SLITRK5 | c.1785C>A p.P595= | Silent (SNP) | VAF 6/143 reads (4%) | catalogued as rs1280614048, COSV61525462; called by muse, mutect2
- SNTB1 | c.1131C>T p.A377= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as rs1325358736; called by muse, mutect2
- SYT8 | c.258C>T p.S86= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs753054817; called by muse, mutect2
- SYT9 | c.1362C>T p.G454= | Silent (SNP) | VAF 16/240 reads (7%) | catalogued as rs770670655, COSV100607572; called by muse, mutect2
- TSHR | c.1065C>T p.F355= | Silent (SNP) | VAF 56/799 reads (7%) | catalogued as COSV53330154; called by muse, mutect2
- ACSM2A | c.597-228A>T | Intron (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- CDH6 | c.1882+77T>A | Intron (SNP) | VAF 7/110 reads (6%) | catalogued as rs1436818856; called by muse, mutect2
- CLCN1 | c.*35G>T | 3'UTR (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- CRY2 | chr11:45847439 del C | 5'Flank (DEL) | VAF 3/29 reads (10%) | catalogued as COSV69889077; called by mutect2, pindel
- FRMD8P1 | n.384G>A | RNA (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- GABRA1 | c.1060-42C>T | Intron (SNP) | VAF 12/134 reads (9%) | catalogued as rs748499503; called by muse, mutect2
- GFRA1 | c.-42G>C | 5'UTR (SNP) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- GVINP1 | n.3901A>G | RNA (SNP) | VAF 7/199 reads (4%) | called by muse, mutect2
- HDHD5-AS1 | n.440-26A>G | Intron (SNP) | VAF 24/336 reads (7%) | called by muse, mutect2
- NDUFV1 | chr11:67604653 G>C | 5'Flank (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- PCP4 | c.-26G>T | 5'UTR (SNP) | VAF 20/246 reads (8%) | catalogued as COSV100150743; called by muse, mutect2
- PLCL1 | c.241-81804G>A | Intron (SNP) | VAF 17/276 reads (6%) | catalogued as rs1026321537; called by muse, mutect2
- PMAIP1 | c.*25G>A | 3'UTR (SNP) | VAF 22/417 reads (5%) | called by muse, mutect2
- SPATA31D5P | n.167T>A | RNA (SNP) | VAF 22/396 reads (6%) | catalogued as rs1391120857; called by muse, mutect2
- TTN | c.10303+2476G>A | Intron (SNP) | VAF 9/89 reads (10%) | catalogued as rs771709418, COSV100621613; called by muse, mutect2, varscan2
- ZNF423 | c.*19A>T | 3'UTR (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- ZNF467 | chr7:149776993 ins G | 5'Flank (INS) | VAF 21/99 reads (21%) | catalogued as rs748030684; called by mutect2, varscan2
